Gene-level copy-number profile of tumor specimen TCGA-36-1580-01A from TCGA case TCGA-36-1580, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 82.1 years (29,992 days).
Specimen TCGA-36-1580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f14c674a-b25b-4929-b28b-4ba9ff78eb17.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1580-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b84b866-ef5e-42e9-88cd-2f5ec70b058a

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,454; copy number 2: 5,073; copy number 3: 9,472; copy number 4: 8,373; copy number 5: 19,751; copy number 6: 10,357; copy number 7: 1,342; copy number 8: 1,481; copy number 9: 1,302; copy number 10: 280; copy number 11: 678; copy number 12: 11; copy number 13: 119; copy number 14: 49; copy number 15: 56; copy number 17: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1580-01): tumor purity 0.53, ploidy 4.6, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:11,157,455–12,021,508, 9 genes (within-gene range 0–2): RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1.
- chr17:12,036,496–12,036,637, 1 gene: RNU11-2P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 919 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,129,464–42,035,925, 111 genes, copy number 13 (within-gene range 9–13) (broad region; genes not listed).
- chr1:91,260,766–93,554,661, 55 genes, copy number 15: HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P, BRDT, EPHX4, LPCAT2BP, SETSIP, BTBD8, GAPDHP46, PRKAR1AP1, AC104836.1, AL663109.1, C1orf146, ACTBP12, GLMN, RPAP2, RN7SL824P, GFI1, EVI5, AL354890.1, HMGB3P9, RNU4-59P, AC104332.1, H3P3, CCNJP2, RPL5, DIPK1A, SNORD21, SNORA66, AL162740.1, AL449283.1, RNU6-970P, RN7SL692P, AC093577.1, RNU6-210P, RN7SKP123, Y_RNA, MTF2, TMED5, CCDC18, AC126124.2, AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53.
- chr1:93,592,199–93,605,573, 1 gene, copy number 15: BCAR3-AS1.
- chr9:32,540,544–32,820,350, 11 genes, copy number 12: TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA.
- chr11:68,312,591–68,874,542, 8 genes, copy number 13: LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701.
- chr11:83,286,120–83,423,516, 3 genes, copy number 17: AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 17: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr12:66,767–27,972,733, 722 genes, copy number 11–14 (broad region; genes not listed).
- chr12:28,163,298–28,319,463, 5 genes, copy number 11–14: AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P.

Autosomal genes at a single copy (total copy number 1): 701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
